CCDI case PBBVNT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d8b5c13b-8d08-4cca-9f50-527e9961487a

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.5 years (2,372 days).

Biospecimens (4 samples)
- Samples 0DIABZ, 0DIAC3 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIACE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIDTU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
